Somatic mutation profile of tumor specimen 0DE5R0 from CCDI case PBBPNS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pineoblastoma; Tissue or organ of origin: Pineal gland; Age at diagnosis: 18.3 years (6,694 days).
Specimen 0DE5R0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 885649fa-9d89-4177-8d86-d8f800b67732.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DE5NC (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f729880b-2825-47b1-b556-3dc68535668f

The open-access MAF lists 22 somatic variants for this specimen: 16 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Intron 3, Silent 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AEBP1 | c.3298G>A p.E1100K | Missense Mutation (SNP) | VAF 263/668 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs750597902, COSV56256830; called by muse, mutect2, varscan2
- EMC2 | c.377G>C p.R126P | Missense Mutation (SNP) | VAF 38/383 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749642246, COSV55207965; called by muse, mutect2
- GNPTG | c.22C>T p.L8F | Missense Mutation (SNP) | VAF 139/307 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs1292636769; called by muse, mutect2, varscan2
- SERPING1 | c.192C>G p.S64R | Missense Mutation (SNP) | VAF 22/585 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs1383635080; called by muse, mutect2
- SLC5A1 | c.620A>T p.Q207L | Missense Mutation (SNP) | VAF 208/476 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV56687864; called by muse, varscan2
- SLC7A11 | c.661T>G p.F221V | Missense Mutation (SNP) | VAF 210/526 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as COSV54933800; called by muse, mutect2, varscan2
- UBN2 | c.1078T>C p.C360R | Missense Mutation (SNP) | VAF 85/517 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as rs367648509; called by muse, mutect2, varscan2
- ZNF514 | c.578A>G p.N193S | Missense Mutation (SNP) | VAF 133/384 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs760752906; called by muse, mutect2, varscan2
- APTX | c.773A>T p.H258L | Missense Mutation (SNP) | VAF 115/490 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- CDK8 | c.524G>A p.G175D | Missense Mutation (SNP) | VAF 116/235 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DPF1 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 22/302 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ESYT3 | c.2285T>C p.V762A | Missense Mutation (SNP) | VAF 55/520 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- GBP6 | c.1837A>G p.K613E | Missense Mutation (SNP) | VAF 194/666 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- NBDY | c.95C>G p.P32R | Missense Mutation (SNP) | VAF 255/275 reads (93%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- ROBO3 | c.3476C>T p.S1159L | Missense Mutation (SNP) | VAF 234/705 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SPEG | c.3728A>T p.H1243L | Missense Mutation (SNP) | VAF 24/173 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- GAS1 | c.81G>T p.L27= | Silent (SNP) | VAF 102/274 reads (37%) | called by muse, mutect2, varscan2
- NHSL2 | c.2127T>C p.G709= (on ENST00000510661; = p.X1075_splice on NM_001013627.2) | Silent (SNP) | VAF 24/95 reads (25%) | called by muse, mutect2, varscan2
- H3-3B | c.283-25A>G | Intron (SNP) | VAF 73/178 reads (41%) | catalogued as COSV99637932; called by muse, mutect2, varscan2
- IKZF1 | c.160+100G>A | Intron (SNP) | VAF 6/16 reads (38%) | catalogued as rs971896120; called by mutect2, varscan2
- LRCOL1 | c.*67C>A | 3'UTR (SNP) | VAF 100/253 reads (40%) | called by muse, mutect2, varscan2
- NACA | c.382-16A>G | Intron (SNP) | VAF 117/199 reads (59%) | catalogued as rs776757899; called by muse, varscan2
